Somatic mutation profile of tumor specimen MMRF_2519_1_BM_CD138pos (aliquot MMRF_2519_1_BM_CD138pos_T1_KHS5U_L12920) from MMRF case MMRF_2519, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.5 years (24,648 days).
Specimen MMRF_2519_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6833bc6e-c1c7-4341-b55c-d86320996326.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2519_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2519_1_PB_WBC_C3_KHS5U_L12921; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f237049-f9d2-42f3-a215-50b39e0bdc00

The open-access MAF lists 87 somatic variants for this specimen: 33 protein-altering or splice-affecting, 9 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 27, Silent 9, Intron 6, RNA 4, 5'Flank 4, 5'UTR 3, 3'Flank 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AARS1 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138490305, COSV55747234; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCK1 | c.1016C>T p.T339M | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs147082749; called by muse, mutect2, varscan2
- ADPGK | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 17/484 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1428195788; called by muse, mutect2
- CCDC88A | c.4480G>A p.D1494N (on ENST00000436346 / NM_001365480.1; = p.D1466N on NM_018084.5) | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV55070599; called by muse, mutect2, varscan2
- H3-4 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs757564822, COSV64210620, COSV64210829; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.323A>C p.H108P (on ENST00000354667 / NM_031243.3; = p.H96P on NM_002137.4) | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV61159404; called by muse, mutect2, varscan2
- IGHV1-69 | c.269C>G p.T90S | Missense Mutation (SNP) | VAF 82/156 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.361); catalogued as rs544777113; called by muse, mutect2, varscan2
- IGHV2-70 | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs757180345; called by muse, varscan2
- IGHV2-70 | c.181C>G p.P61A | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.211); catalogued as rs377540429; called by muse, varscan2
- IGHV2-70 | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs368945949; called by muse, varscan2
- IGLV3-1 | c.65A>C p.E22A | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.018); catalogued as rs528877557; called by muse, varscan2
- IGLV3-1 | c.118A>C p.T40P | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as rs189772470; called by muse, varscan2
- IGSF10 | c.2402C>T p.A801V | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs145028765, COSV99176933; called by muse, mutect2, varscan2
- OR51I2 | c.64A>G p.S22G | Missense Mutation (SNP) | VAF 19/265 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as rs965338906; called by muse, mutect2
- PCDHA8 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 52/380 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.947); catalogued as rs781796924, COSV65335014; called by muse, mutect2, varscan2
- SLC6A11 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.027); catalogued as rs1451859570; called by muse, mutect2, varscan2
- TMEM81 | c.184G>A p.V62I | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs150799197; called by muse, mutect2, varscan2
- ZNF563 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 34/145 reads (23%) | catalogued as rs1448715984, COSV53372364; called by muse, mutect2, varscan2
- ADPGK | c.1120G>T p.D374Y | Missense Mutation (SNP) | VAF 13/389 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2
- ALPP | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ASTN2 | c.2267T>C p.V756A (on ENST00000313400 / NM_001365069.1; = p.V705A on NM_014010.5) | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEGAIN | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- COL22A1 | c.584C>G p.A195G | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FOXA1 | c.673A>C p.N225H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HDAC9 | c.1460T>G p.L487R | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- JAKMIP3 | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- LINC00687 | n.564-2A>T | Splice Site (SNP) | VAF 64/207 reads (31%) | called by muse, mutect2, varscan2
- NPBWR1 | c.233A>G p.N78S | Missense Mutation (SNP) | VAF 68/224 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OBSCN | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- PCDHGC5 | c.1307A>G p.K436R | Missense Mutation (SNP) | VAF 61/295 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRTG | c.2023T>C p.Y675H | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.009); called by muse, mutect2
- SHC3 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 75/264 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- THOC3 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- FSHB | c.168G>T p.V56= | Silent (SNP) | VAF 28/118 reads (24%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.141G>T p.G47= | Silent (SNP) | VAF 46/116 reads (40%) | catalogued as rs563686192; called by muse, varscan2
- IZUMO3 | c.87A>C p.I29= | Silent (SNP) | VAF 54/135 reads (40%) | called by muse, mutect2, varscan2
- JAG2 | c.192C>T p.H64= | Silent (SNP) | VAF 9/111 reads (8%) | called by muse, mutect2
- KCNQ1 | c.786G>A p.L262= | Silent (SNP) | VAF 20/106 reads (19%) | called by muse, mutect2, varscan2
- PRR12 | c.72C>T p.P24= (on ENST00000615927; = p.P845= on NM_020719.3) | Silent (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- SIGLEC1 | c.930C>T p.G310= | Silent (SNP) | VAF 57/179 reads (32%) | catalogued as rs757586903, COSV52458597; called by muse, mutect2, varscan2
- UGT3A2 | c.504T>G p.T168= | Silent (SNP) | VAF 49/188 reads (26%) | called by muse, mutect2, varscan2
- WHRN | c.348G>T p.L116= | Silent (SNP) | VAF 40/210 reads (19%) | catalogued as rs775775788; called by muse, mutect2, varscan2
- ABLIM2 | chr4:7965725 C>T | 3'Flank (SNP) | VAF 20/270 reads (7%) | catalogued as rs533475878; called by muse, mutect2
- AC106795.1 | n.1108G>A | RNA (SNP) | VAF 24/234 reads (10%) | called by mutect2, varscan2
- ADAM19 | c.*132A>G | 3'UTR (SNP) | VAF 33/139 reads (24%) | called by muse, mutect2, varscan2
- AKR1B1P6 | n.190G>A | RNA (SNP) | VAF 64/103 reads (62%) | catalogued as rs1251349372; called by muse, mutect2, varscan2
- ANAPC13 | c.*565T>G | 3'UTR (SNP) | VAF 31/162 reads (19%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499222 C>G | 5'Flank (SNP) | VAF 20/58 reads (34%) | catalogued as rs765893010; called by muse, varscan2
- AP000769.5 | chr11:65499307 T>A | 5'Flank (SNP) | VAF 32/108 reads (30%) | called by muse, varscan2
- ARHGAP31 | c.*702T>C | 3'UTR (SNP) | VAF 31/132 reads (23%) | called by muse, mutect2, varscan2
- ARL5A | c.*3842dup | 3'UTR (INS) | VAF 28/90 reads (31%) | called by mutect2, pindel, varscan2
- CLEC3A | c.*111G>T | 3'UTR (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- CRTC2 | c.608-96A>G | Intron (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- DALRD3 | chr3:49021222 C>T | 5'Flank (SNP) | VAF 56/303 reads (18%) | called by muse, mutect2, varscan2
- DENND6A | c.1620+49_1620+54del | Intron (DEL) | VAF 59/243 reads (24%) | called by mutect2, pindel, varscan2
- DIPK2A | c.-134C>T | 5'UTR (SNP) | VAF 28/93 reads (30%) | catalogued as rs1460444573; called by muse, mutect2, varscan2
- DNAJC21 | c.-161G>A | 5'UTR (SNP) | VAF 6/58 reads (10%) | catalogued as COSV57761008; called by muse, varscan2
- EFCAB11 | c.*1266C>T | 3'UTR (SNP) | VAF 41/149 reads (28%) | catalogued as rs868459127; called by muse, mutect2, varscan2
- FIGN | c.*871G>A | 3'UTR (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- GLRA3 | c.*2818T>C | 3'UTR (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- GPR132 | c.*80C>T | 3'UTR (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- HLX | c.593-122G>T | Intron (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- IGKV1-13 | n.225G>C | RNA (SNP) | VAF 53/167 reads (32%) | catalogued as rs770111459; called by muse, mutect2, varscan2
- KLF13 | c.*4159del | 3'UTR (DEL) | VAF 18/102 reads (18%) | called by mutect2, pindel, varscan2
- LINC01460 | n.2072C>A | RNA (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- MARK2 | c.*101G>T | 3'UTR (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- NAALADL2 | c.1896+28109G>T | Intron (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- NOX4 | c.*1111A>C | 3'UTR (SNP) | VAF 142/291 reads (49%) | called by muse, mutect2, varscan2
- NUDT16 | c.*4630G>A | 3'UTR (SNP) | VAF 5/81 reads (6%) | called by muse, mutect2
- OGG1 | c.*325G>A | 3'UTR (SNP) | VAF 32/100 reads (32%) | called by muse, mutect2, varscan2
- ORMDL3 | c.*1503C>G | 3'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- PAX5 | c.*5865G>A | 3'UTR (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- PEG10 | c.*4297A>G | 3'UTR (SNP) | VAF 56/109 reads (51%) | called by muse, mutect2, varscan2
- PHTF2 | c.*108T>C | 3'UTR (SNP) | VAF 68/313 reads (22%) | called by muse, mutect2, varscan2
- PIK3IP1 | c.*1332C>G | 3'UTR (SNP) | VAF 42/166 reads (25%) | called by muse, mutect2
- PPP2R2A | c.*291T>C | 3'UTR (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- PPP4R3A | chr14:91509908 G>A | 5'Flank (SNP) | VAF 6/53 reads (11%) | catalogued as rs994336653; called by muse, mutect2
- PRSS37 | c.177-57T>G | Intron (SNP) | VAF 28/135 reads (21%) | called by muse, mutect2, varscan2
- PYGM | c.1000-13C>A | Intron (SNP) | VAF 72/123 reads (59%) | catalogued as rs779002909; called by muse, mutect2, varscan2
- SGPP1 | c.*549T>G | 3'UTR (SNP) | VAF 46/154 reads (30%) | called by muse, mutect2, varscan2
- SGPP1 | c.*49C>A | 3'UTR (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- SLITRK2 | c.-3579T>C | 5'UTR (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- SRF | c.*1808G>A | 3'UTR (SNP) | VAF 42/126 reads (33%) | catalogued as rs1007340652; called by muse, mutect2, varscan2
- STS | c.*2687C>T | 3'UTR (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- TMEM72 | c.*253C>A | 3'UTR (SNP) | VAF 10/97 reads (10%) | catalogued as rs1014727683; called by muse, mutect2, varscan2
- USP22 | c.*860G>T | 3'UTR (SNP) | VAF 78/236 reads (33%) | called by muse, mutect2, varscan2
- ZFP37 | c.*3407A>G | 3'UTR (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
